Somatic mutation profile of tumor specimen TARGET-40-PASNZV-01A (aliquot TARGET-40-PASNZV-01A-01D) from TARGET case TARGET-40-PASNZV, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.3 years (5,947 days).
Specimen TARGET-40-PASNZV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0675c2c-7612-444b-8ede-9166fc118fc3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PASNZV-10A (Blood Derived Normal), aliquot TARGET-40-PASNZV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26b1b503-962c-4a49-9a3b-475c43f3ca6d

The open-access MAF lists 50 somatic variants for this specimen: 31 protein-altering or splice-affecting, 7 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 7, Intron 6, RNA 3, 3'UTR 2, Splice Region 2, Nonsense Mutation 2, Frame Shift Ins 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 70/109 reads (64%) | hotspot (GDC flag); catalogued as rs121913303, CM961229, COSV57297124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAAF1 | c.1076C>G p.A359G | Missense Mutation (SNP) | VAF 65/414 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.057); catalogued as COSV100533837; called by muse, mutect2, varscan2
- DYTN | c.755G>T p.C252F | Missense Mutation (SNP) | VAF 285/422 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770233978; called by muse, mutect2, varscan2
- FOXR1 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 71/563 reads (13%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.732); catalogued as rs782323250, COSV57652367; called by muse, mutect2, varscan2
- GRID2 | c.1295A>G p.K432R | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56197514; called by muse, mutect2
- INTS6L | c.1468A>G p.K490E | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.298); catalogued as rs1556528639; called by muse, mutect2, varscan2
- NCR3LG1 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 28/221 reads (13%) | catalogued as rs775491086; called by muse, mutect2, varscan2
- PMPCB | c.674A>G p.D225G | Missense Mutation (SNP) | VAF 187/263 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50787211; called by muse, mutect2, varscan2
- SAGE1 | c.1693G>T p.G565C | Missense Mutation (SNP) | VAF 36/286 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100187874; called by muse, mutect2, varscan2
- SRRM2 | c.5550G>T p.K1850N | Missense Mutation (SNP) | VAF 59/254 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100071195; called by muse, mutect2, varscan2
- TG | c.2645C>T p.S882F | Missense Mutation (SNP) | VAF 230/452 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV55079808; called by muse, varscan2
- TP53 | c.358_362dup p.V122Sfs*3 | Frame Shift Ins (INS) | VAF 158/264 reads (60%) | catalogued as COSV99372028; called by mutect2, pindel, varscan2
- ACSBG2 | c.477G>C p.E159D | Missense Mutation (SNP) | VAF 138/651 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- CHTF18 | c.1104+5G>A | Splice Region (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- FOXF2 | c.435G>T p.K145N | Missense Mutation (SNP) | VAF 30/664 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GGPS1 | c.615T>G p.C205W | Missense Mutation (SNP) | VAF 110/464 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM7A | c.2770C>T p.R924C | Missense Mutation (SNP) | VAF 224/285 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLF17 | c.113T>A p.M38K | Missense Mutation (SNP) | VAF 58/314 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KRTAP4-4 | c.143C>G p.P48R | Missense Mutation (SNP) | VAF 130/614 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KRTAP5-3 | c.112C>G p.P38A | Missense Mutation (SNP) | VAF 250/1201 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MOV10L1 | c.615del p.L206Wfs*4 | Frame Shift Del (DEL) | VAF 127/425 reads (30%) | called by mutect2, pindel, varscan2
- NR1H3 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- NTN1 | c.599A>C p.E200A | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PAXIP1 | c.2066C>G p.P689R | Missense Mutation (SNP) | VAF 27/668 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PYCR3 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 162/736 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- TBXT | c.609C>T p.I203= | Splice Region (SNP) | VAF 67/229 reads (29%) | called by muse, mutect2, varscan2
- TENM1 | c.1807G>T p.G603C | Missense Mutation (SNP) | VAF 78/644 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- TG | c.2116G>A p.V706I | Missense Mutation (SNP) | VAF 549/971 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIML1 | c.972T>A p.F324L | Missense Mutation (SNP) | VAF 43/403 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TTN | c.34557G>T p.K11519N (on ENST00000591111; = p.K10592N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/524 reads (6%) | PolyPhen benign (0.055); called by muse, mutect2
- TYW1 | c.559C>A p.H187N | Missense Mutation (SNP) | VAF 395/598 reads (66%) | SIFT tolerated (0.27); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- CA12 | c.264C>G p.L88= | Silent (SNP) | VAF 14/421 reads (3%) | called by muse, mutect2
- GAS7 | c.6C>T p.S2= | Silent (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- GJA5 | c.1024C>A p.R342= | Silent (SNP) | VAF 196/969 reads (20%) | catalogued as COSV99605512; called by muse, mutect2, varscan2
- MEPCE | c.1272C>T p.Y424= | Silent (SNP) | VAF 69/331 reads (21%) | catalogued as rs199916162; called by muse, mutect2, varscan2
- NR4A2 | c.609C>T p.N203= | Silent (SNP) | VAF 35/335 reads (10%) | catalogued as rs1423537757; called by muse, mutect2, varscan2
- PYCR3 | c.444G>A p.E148= | Silent (SNP) | VAF 114/513 reads (22%) | catalogued as rs747162491; called by muse, mutect2, varscan2
- TMEM121B | c.1656C>G p.S552= | Silent (SNP) | VAF 16/115 reads (14%) | called by muse, mutect2, varscan2
- AC073648.3 | n.265G>C | RNA (SNP) | VAF 102/485 reads (21%) | called by muse, mutect2, varscan2
- C22orf34 | n.307C>A | RNA (SNP) | VAF 118/316 reads (37%) | catalogued as rs770690001; called by muse, mutect2, varscan2
- HEATR9 | c.510+58A>G | Intron (SNP) | VAF 10/268 reads (4%) | called by muse, mutect2
- HSPA12A | c.*41C>T | 3'UTR (SNP) | VAF 83/123 reads (67%) | called by muse, mutect2, varscan2
- POLR2D | c.73+96_73+117del | Intron (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel
- PSMC1P5 | n.49G>T | RNA (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- PYCR3 | c.337-106G>A | Intron (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
- RGS7 | c.*59C>T | 3'UTR (SNP) | VAF 101/371 reads (27%) | catalogued as rs754532001, COSV58530804; called by muse, mutect2, varscan2
- SF3A2 | c.405+40A>G | Intron (SNP) | VAF 46/355 reads (13%) | called by muse, mutect2, varscan2
- SIGLEC7 | c.1125-57C>G | Intron (SNP) | VAF 49/117 reads (42%) | called by muse, mutect2, varscan2
- TTC4 | c.111+108C>T | Intron (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- ZNF773 | chr19:57513103 C>G | 3'Flank (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
